Somatic mutation profile of tumor specimen ALCH-B1QB-TTR1-A (aliquot ALCH-B1QB-TTR1-A-9-0-D-A80D-36) from ALCHEMIST case ALCH-B1QB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,720 days).
Specimen ALCH-B1QB-TTR1-A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 579a7978-d5f9-4321-bd64-76f94e3fcacd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1QB-NB1-A (Blood Derived Normal), aliquot ALCH-B1QB-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7fbb0af-c19b-429a-81b2-5aa01be3e869

The open-access MAF lists 41 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Intron 6, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 95/675 reads (14%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 94/910 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADCY5 | c.2941G>A p.A981T | Missense Mutation (SNP) | VAF 36/377 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as rs571005355; called by muse, mutect2
- DLL1 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 107/1751 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs759299011, COSV64538240; called by muse, mutect2
- FAM171B | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.24); catalogued as rs369639086; called by muse, mutect2
- PCDHA1 | c.1700C>T p.A567V | Missense Mutation (SNP) | VAF 58/1552 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs368549830; called by muse, mutect2
- PCDHGA12 | c.1025A>T p.D342V | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as rs1210499024, COSV52747084; called by muse, mutect2, varscan2
- ATXN7L2 | c.1058G>C p.S353T | Missense Mutation (SNP) | VAF 58/768 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); called by muse, mutect2
- CCDC28A | c.78A>C p.K26N | Missense Mutation (SNP) | VAF 16/454 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); called by muse, mutect2
- CYP2A7 | c.1069C>A p.H357N | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2
- DNAH9 | c.12069T>G p.H4023Q | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.017); called by muse, mutect2
- ECE1 | c.1433G>T p.S478I | Missense Mutation (SNP) | VAF 50/805 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2
- GART | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GCC1 | c.2102C>T p.A701V | Missense Mutation (SNP) | VAF 22/489 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- KRTAP13-2 | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MAGEB18 | c.676A>T p.M226L | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.914); called by muse, mutect2
- RBM47 | c.463A>T p.I155F | Missense Mutation (SNP) | VAF 52/562 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.456); called by muse, mutect2
- SPAG17 | c.1869G>A p.M623I | Missense Mutation (SNP) | VAF 15/390 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.013); called by muse, mutect2
- TENM2 | c.3125C>G p.A1042G (on ENST00000518659 / NM_001122679.2; = p.A810G on NM_001080428.3) | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2
- TRIM3 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- UMODL1 | c.2989A>C p.K997Q (on ENST00000408910 / NM_001004416.2; = p.K1125Q on NM_173568.3) | Missense Mutation (SNP) | VAF 54/1112 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); called by muse, mutect2
- USP36 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 163/1331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP43 | c.2776C>T p.P926S | Missense Mutation (SNP) | VAF 54/580 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ZNF292 | c.2615T>C p.L872P | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- CAVIN1 | c.339G>A p.K113= | Silent (SNP) | VAF 98/1215 reads (8%) | called by muse, mutect2
- CCDC86 | c.90G>A p.R30= | Silent (SNP) | VAF 58/606 reads (10%) | called by muse, mutect2
- COL6A5 | c.7326G>A p.V2442= (on ENST00000312481; = p.V2438= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- FLII | c.2097C>A p.L699= | Silent (SNP) | VAF 55/418 reads (13%) | called by muse, mutect2, varscan2
- GPR142 | c.1059C>T p.G353= | Silent (SNP) | VAF 28/281 reads (10%) | called by muse, mutect2, varscan2
- MAP3K9 | c.1998G>T p.L666= | Silent (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- MINDY2 | c.15C>G p.P5= | Silent (SNP) | VAF 36/849 reads (4%) | called by muse, mutect2
- TADA3 | c.529C>T p.L177= | Silent (SNP) | VAF 44/447 reads (10%) | catalogued as rs1559720807; called by muse, mutect2
- TNS1 | c.852C>T p.D284= | Silent (SNP) | VAF 18/292 reads (6%) | called by muse, mutect2
- ABI3BP | c.1576+14077G>A | Intron (SNP) | VAF 20/428 reads (5%) | catalogued as rs1293016885; called by muse, mutect2
- CCNF | c.1219-40C>G | Intron (SNP) | VAF 63/615 reads (10%) | called by muse, mutect2, varscan2
- COL9A3 | c.1402-47G>A | Intron (SNP) | VAF 46/378 reads (12%) | called by muse, mutect2, varscan2
- LILRB2 | c.1360+31C>T | Intron (SNP) | VAF 37/230 reads (16%) | catalogued as rs565888183; called by muse, mutect2, varscan2
- LINC00840 | n.293G>A | RNA (SNP) | VAF 113/658 reads (17%) | called by muse, mutect2, varscan2
- LINC02876 | n.499T>A | RNA (SNP) | VAF 25/251 reads (10%) | called by muse, mutect2
- LYRM9 | c.219+133C>G | Intron (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- RIT2 | c.426+2859G>T | Intron (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
